Gene-level copy-number profile of tumor specimen ALCH-B2LL-TTP1-A from ALCHEMIST case ALCH-B2LL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,845 days).
Specimen ALCH-B2LL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c881fe8-de10-4009-83c2-9124913b11e6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2LL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/fc1e7b2c-2b23-46c4-aa7e-e8b84943762e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 6,382; copy number 2: 43,290; copy number 3: 7,156; copy number 4: 1,378; copy number 5: 531; copy number 6: 123; copy number 8: 1; copy number 9: 1; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:268,982–270,175, 2 genes: AC079140.3, AC079140.5.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr10:14,986,942–14,987,515, 1 gene (within-gene range 0–3): OR7E110P.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr14:18,588,274–18,588,315, 1 gene (within-gene range 0–6): CR383656.9.
- chr14:18,614,388–18,637,421, 5 genes: CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr16:89,088,375–89,237,141, 9 genes: ACSF3, AC135782.3, LINC00304, LINC02138, CDH15, SLC22A31, AC009113.1, ZNF778, AC009113.2.
- chr16:89,268,104–89,273,044, 1 gene (within-gene range 0–1): AC137932.3.
- chr19:42,752,686–43,171,515, 11 genes (within-gene range 0–2): PSG8, CEACAMP6, PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 654 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,099,330–179,358,680, 10 genes, copy number 5: ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1.
- chr1:202,096,759–202,096,978, 1 gene, copy number 8: CRIP1P3.
- chr7:129,830,732–131,948,953, 58 genes, copy number 5: UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1.
- chr7:132,648,794–142,301,432, 182 genes, copy number 5–6 (broad region; genes not listed).
- chr7:142,855,061–143,936,279, 52 genes, copy number 5: EPHB6, TRPV6, AC245427.1, TRPV5, LLCFC1, KEL, OR9A2, OR9P1P, OR6V1, OR6W1P, PIP, TAS2R39, AC073342.1, TAS2R40, AC073342.2, GSTK1, TMEM139-AS1, TMEM139, CASP2, RN7SL535P, RN7SL481P, HINT1P1, CLCN1, FAM131B, AC093673.2, AC093673.1, ZYX, MIR6892, EPHA1, EPHA1-AS1, TAS2R62P, TAS2R60, TAS2R41, OR2R1P, OR10AC1, AC073264.1, PAICSP5, CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C, RNU6-267P, CTAGE6, AC099548.2, PAICSP6, AC099548.1, TCAF2P1, TCAF1, OR2F2.
- chr14:18,395,626–18,412,264, 1 gene, copy number 5: CR383658.2.
- chr14:18,555,677–18,596,310, 3 genes, copy number 6 (within-gene range 0–6): CR383656.10, CR383656.7, CR383656.13.
- chr14:34,485,979–35,932,325, 49 genes, copy number 5 (within-gene range 3–5): RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2.
- chr14:54,842,008–54,902,826, 1 gene, copy number 5 (within-gene range 3–5): GCH1.
- chr14:54,878,113–55,027,105, 3 genes, copy number 5 (within-gene range 3–5): MIR4308, FDPSP3, WDHD1.
- chr19:31,421,997–33,341,984, 50 genes, copy number 5: AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50.
- chr19:33,795,933–34,355,566, 11 genes, copy number 6 (within-gene range 2–6): KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A, GARRE1, RPL29P33.
- chr20:48,921,711–50,321,342, 43 genes, copy number 5: ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.
- chr20:50,585,786–61,083,750, 172 genes, copy number 5–6 (broad region; genes not listed).
- chr21:10,328,411–13,120,807, 16 genes, copy number 5: AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:18,715,815–18,757,906, 2 genes, copy number 9–14: PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 5,501. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
